CCDI case PBBIJB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5dac57fd-bcbf-4767-9a33-a18b6828d8c1

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 17.1 years (6,257 days).

Biospecimens (3 samples)
- Sample 0D9CM7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9CML: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9CMM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
